Somatic mutation profile of tumor specimen MMRF_1736_1_BM_CD138pos (aliquot MMRF_1736_1_BM_CD138pos_T1_KBS5U_K11321) from MMRF case MMRF_1736, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 79.2 years (28,913 days).
Specimen MMRF_1736_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2fdd91e-6ecc-425e-8e14-007e92efd51c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1736_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1736_1_PB_CD3pos_C2_KBS5U_K11322; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/52c1a02e-d769-4885-8ecc-f7ca6923a507

The open-access MAF lists 90 somatic variants for this specimen: 37 protein-altering or splice-affecting, 15 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, 3'UTR 21, Silent 15, Intron 10, 3'Flank 3, Nonsense Mutation 3, Frame Shift Ins 2, 5'Flank 2, In Frame Del 1, 5'UTR 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 44/105 reads (42%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CDHR4 | c.403+5G>A | Splice Region (SNP) | VAF 46/98 reads (47%) | catalogued as rs1358577880; called by muse, mutect2, varscan2
- EML2 | c.95G>A p.C32Y | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.037); catalogued as COSV68242372; called by muse, mutect2, varscan2
- HSD3B2 | c.398A>G p.Y133C | Missense Mutation (SNP) | VAF 58/111 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as rs768064787; called by muse, mutect2, varscan2
- IGHJ4 | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 47/70 reads (67%) | PolyPhen benign (0.096); catalogued as rs560574717; called by muse, varscan2
- IGKV1-8 | c.103A>G p.T35A | Missense Mutation (SNP) | VAF 80/80 reads (100%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs551884530; called by muse, varscan2
- INO80B | c.767dup p.A257Rfs*75 | Frame Shift Ins (INS) | VAF 13/39 reads (33%) | catalogued as rs761589557; called by mutect2, varscan2
- ITSN1 | c.1351C>T p.R451W | Missense Mutation (SNP) | VAF 110/227 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs757736852, COSV101180508; called by muse, mutect2, varscan2
- KIT | c.2075C>A p.S692* | Nonsense Mutation (SNP) | VAF 34/78 reads (44%) | catalogued as COSV55407451; called by muse, mutect2, varscan2
- MRPS15 | c.207_209del p.S70del | In Frame Del (DEL) | VAF 32/52 reads (62%) | catalogued as rs774120845; called by mutect2, pindel, varscan2
- NRIP1 | c.2550G>C p.K850N | Missense Mutation (SNP) | VAF 122/243 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.626); catalogued as COSV100012365; called by muse, mutect2, varscan2
- PDGFA | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1271034775, COSV63280108; called by muse, mutect2, varscan2
- SENP5 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 114/245 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs552471366; called by muse, mutect2, varscan2
- SHANK1 | c.6304G>A p.D2102N | Missense Mutation (SNP) | VAF 122/256 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1194197722, COSV53244863; called by muse, mutect2, varscan2
- SPTB | c.6392C>T p.P2131L | Missense Mutation (SNP) | VAF 67/134 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs200556500; called by muse, mutect2, varscan2
- THNSL1 | c.1974C>G p.C658W | Missense Mutation (SNP) | VAF 60/123 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs936250765; called by muse, mutect2, varscan2
- UNC80 | c.7183C>T p.R2395* | Nonsense Mutation (SNP) | VAF 16/31 reads (52%) | catalogued as rs1254716249, COSV55885581; called by muse, mutect2, varscan2
- ZNF750 | c.1621G>A p.A541T | Missense Mutation (SNP) | VAF 63/142 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV53959594; called by muse, mutect2, varscan2
- ANKRD50 | c.4097A>T p.N1366I | Missense Mutation (SNP) | VAF 117/249 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- ATXN2 | c.377C>G p.P126R | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.114); called by muse, mutect2
- C12orf40 | c.790C>T p.H264Y | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CCDC66 | c.1310_1319+40del p.X437_splice (on ENST00000394672 / NM_001353147.1; = p.X403_splice on NM_001012506.5 and 6 other RefSeq transcripts) | Splice Site (DEL) | VAF 36/82 reads (44%) | called by mutect2, pindel
- CTNND2 | c.2856C>G p.S952R | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- GATA6 | c.89G>T p.R30L | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GRIA4 | c.1051C>G p.Q351E | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2
- GRK5 | c.320C>T p.T107I | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- IGKV1D-8 | c.124A>G p.T42A | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- KYNU | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 76/166 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MALRD1 | c.3637G>A p.A1213T | Missense Mutation (SNP) | VAF 87/205 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- MMGT1 | c.381dup p.S128Ifs*45 | Frame Shift Ins (INS) | VAF 95/100 reads (95%) | called by mutect2, varscan2
- MPP2 | c.1321C>G p.L441V (on ENST00000461854 / NM_001278372.2; = p.L417V on NM_005374.5) | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MRNIP | c.719del p.S240Yfs*95 | Frame Shift Del (DEL) | VAF 74/273 reads (27%) | called by mutect2, pindel, varscan2
- MYB | c.1755_1756insACA p.V585_L586insT | In Frame Ins (INS) | VAF 98/216 reads (45%) | called by mutect2, varscan2
- PTPRB | c.5240C>A p.S1747Y | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- SLITRK1 | c.1970C>A p.S657Y | Missense Mutation (SNP) | VAF 35/35 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- TNS3 | c.2305G>T p.G769C | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- TOP1MT | c.163C>T p.Q55* | Nonsense Mutation (SNP) | VAF 80/81 reads (99%) | called by muse, mutect2, varscan2
- CDC42BPA | c.5082G>A p.P1694= (on ENST00000334218 / NM_001366019.2; = p.P1681= on NM_003607.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 54/117 reads (46%) | catalogued as rs763391096; called by muse, mutect2, varscan2
- CDH9 | c.1104T>C p.A368= | Silent (SNP) | VAF 86/274 reads (31%) | called by muse, mutect2, varscan2
- COL7A1 | c.4149G>A p.G1383= | Silent (SNP) | VAF 32/129 reads (25%) | called by muse, mutect2, varscan2
- CUEDC1 | c.1050G>A p.A350= | Silent (SNP) | VAF 101/175 reads (58%) | catalogued as rs141831048; called by muse, mutect2, varscan2
- IGKV1-8 | c.69G>A p.R23= | Silent (SNP) | VAF 88/89 reads (99%) | catalogued as rs762398056; called by muse, varscan2
- KCNB1 | c.381C>A p.I127= | Silent (SNP) | VAF 138/242 reads (57%) | called by muse, mutect2, varscan2
- MYO3A | c.4365G>A p.L1455= | Silent (SNP) | VAF 85/186 reads (46%) | called by muse, mutect2, varscan2
- OR1M1 | c.111C>T p.V37= | Silent (SNP) | VAF 32/219 reads (15%) | called by muse, mutect2, varscan2
- PPFIA1 | c.1554T>A p.G518= | Silent (SNP) | VAF 44/156 reads (28%) | called by muse, mutect2, varscan2
- RRAGA | c.45G>A p.K15= | Silent (SNP) | VAF 128/249 reads (51%) | catalogued as rs980725965; called by muse, mutect2, varscan2
- SAR1A | c.222T>C p.F74= | Silent (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2
- SMG7 | c.2817C>T p.L939= | Silent (SNP) | VAF 83/188 reads (44%) | called by muse, mutect2, varscan2
- TRIM24 | c.288G>A p.L96= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs1236371814; called by muse, mutect2, varscan2
- ZBTB41 | c.1278T>C p.Y426= | Silent (SNP) | VAF 15/38 reads (39%) | called by muse, mutect2, varscan2
- ZFR2 | c.39C>A p.G13= | Silent (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- ABHD13 | c.*3287G>T | 3'UTR (SNP) | VAF 44/46 reads (96%) | called by muse, mutect2, varscan2
- AGPAT3 | c.*449G>A | 3'UTR (SNP) | VAF 77/148 reads (52%) | catalogued as rs1166062474; called by muse, mutect2, varscan2
- ATP9A | c.*2309C>T | 3'UTR (SNP) | VAF 51/141 reads (36%) | catalogued as rs1030716297; called by muse, mutect2, varscan2
- ATXN7 | c.2661+97G>T | Intron (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- BBX | c.*1015A>G | 3'UTR (SNP) | VAF 42/88 reads (48%) | catalogued as rs1195955088; called by muse, mutect2, varscan2
- BCL7A | chr12:122021189 G>A | 5'Flank (SNP) | VAF 96/176 reads (55%) | called by muse, mutect2, varscan2
- C5orf49 | c.*810C>A | 3'UTR (SNP) | VAF 78/126 reads (62%) | called by muse, mutect2, varscan2
- CAMKV | c.639-9C>T | Intron (SNP) | VAF 44/150 reads (29%) | called by muse, mutect2, varscan2
- CD81 | c.182-296C>T | Intron (SNP) | VAF 8/34 reads (24%) | catalogued as rs372302573; called by muse, varscan2
- CILK1 | c.*663T>A | 3'UTR (SNP) | VAF 53/108 reads (49%) | called by muse, mutect2, varscan2
- COL4A6 | c.15-286A>T | Intron (SNP) | VAF 4/37 reads (11%) | called by muse, mutect2, varscan2
- COL9A1 | c.781-270C>G | Intron (SNP) | VAF 88/162 reads (54%) | called by muse, mutect2, varscan2
- DNAJC16 | chr1:15575875 C>T | 3'Flank (SNP) | VAF 19/40 reads (48%) | called by muse, mutect2, varscan2
- DOCK8 | chr9:213553 T>C | 5'Flank (SNP) | VAF 41/86 reads (48%) | catalogued as rs1475322327; called by muse, mutect2, varscan2
- EIF2S1 | c.*965T>C | 3'UTR (SNP) | VAF 58/119 reads (49%) | called by muse, mutect2, varscan2
- ELAC2 | c.245+79C>T | Intron (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- KCNE5 | c.*82C>T | 3'UTR (SNP) | VAF 9/9 reads (100%) | called by muse, mutect2, varscan2
- KCNK1 | c.356-16546G>A | Intron (SNP) | VAF 47/97 reads (48%) | called by muse, mutect2, varscan2
- KLHDC10 | c.*101G>T | 3'UTR (SNP) | VAF 108/234 reads (46%) | called by muse, mutect2, varscan2
- MGAM | c.4619-12551C>T | Intron (SNP) | VAF 66/140 reads (47%) | called by muse, mutect2, varscan2
- NAV2 | chr11:20120954 G>T | 3'Flank (SNP) | VAF 23/97 reads (24%) | called by muse, mutect2, varscan2
- NPL | c.*603G>A | 3'UTR (SNP) | VAF 55/106 reads (52%) | called by muse, mutect2, varscan2
- NR2F2 | c.*761A>G | 3'UTR (SNP) | VAF 62/111 reads (56%) | called by muse, mutect2, varscan2
- P2RX6 | c.*724G>T | 3'UTR (SNP) | VAF 32/33 reads (97%) | called by muse, mutect2, varscan2
- PEDS1 | c.*1181G>C | 3'UTR (SNP) | VAF 27/65 reads (42%) | called by muse, mutect2, varscan2
- PGGT1B | c.259+126A>C | Intron (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2
- POU2F1 | c.*1300G>T | 3'UTR (SNP) | VAF 37/73 reads (51%) | catalogued as COSV54813992; called by muse, mutect2, varscan2
- POU2F1 | c.*1301A>G | 3'UTR (SNP) | VAF 37/73 reads (51%) | called by muse, mutect2, varscan2
- PPAT | c.*1821A>T | 3'UTR (SNP) | VAF 88/170 reads (52%) | called by muse, varscan2
- RPLP0P2 | n.1291A>G | RNA (SNP) | VAF 29/46 reads (63%) | called by muse, mutect2, varscan2
- SMPD4 | c.-921C>G | 5'UTR (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- SPOCK3 | c.*525T>C | 3'UTR (SNP) | VAF 10/100 reads (10%) | called by muse, mutect2
- SPRING1 | c.*158G>A | 3'UTR (SNP) | VAF 43/95 reads (45%) | called by muse, mutect2, varscan2
- TEAD1 | c.*6690G>C | 3'UTR (SNP) | VAF 13/66 reads (20%) | called by muse, mutect2, varscan2
- TMEM132D | c.1444-1086C>G | Intron (SNP) | VAF 29/62 reads (47%) | called by muse, mutect2, varscan2
- ZBED1 | c.*164C>G | 3'UTR (SNP) | VAF 35/96 reads (36%) | called by mutect2, varscan2
- ZBED1 | c.*163T>C | 3'UTR (SNP) | VAF 32/94 reads (34%) | called by mutect2, varscan2
- ZNF34 | chr8:144772908 G>C | 3'Flank (SNP) | VAF 18/18 reads (100%) | called by muse, mutect2, varscan2
